Somatic mutation profile of tumor specimen TCGA-EJ-A65B-01A (aliquot TCGA-EJ-A65B-01A-12D-A30E-08) from TCGA case TCGA-EJ-A65B, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 55.3 years (20,204 days).
Specimen TCGA-EJ-A65B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2dcd382-1f3c-420c-aabd-37bf01a29848.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65B-10A (Blood Derived Normal), aliquot TCGA-EJ-A65B-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b16c0eb-2e24-459d-b42e-fb2eeb1f1e77

The open-access MAF lists 25 somatic variants for this specimen: 23 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 20, Silent 2, Frame Shift Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCYAP1R1 | c.876T>G p.D292E | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV58441155; called by muse, mutect2, varscan2
- AFF3 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs756890773, COSV57839207; called by muse, mutect2
- ANXA2 | c.151G>A p.V51M | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60315466; called by muse, mutect2
- ASPRV1 | c.861T>A p.D287E | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57227289; called by muse, mutect2, varscan2
- CARMIL3 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1299201756, COSV57724511; called by muse, mutect2
- CKAP5 | c.2855A>G p.D952G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56363690; called by muse, mutect2
- EVC2 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.153); catalogued as COSV60387446; called by muse, mutect2, varscan2
- FAM50B | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV66654444; called by muse, mutect2
- FZD10 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1439601423, COSV57472000; called by muse, mutect2
- LARS2 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55525081; called by muse, mutect2
- LRRK2 | c.2879-1G>A p.X960_splice | Splice Site (SNP) | VAF 13/61 reads (21%) | catalogued as COSV54142630; called by muse, mutect2, varscan2
- MAP1A | c.3416G>C p.R1139T | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); catalogued as rs750541025, COSV55805547; called by muse, mutect2
- MLH1 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367654552, CD015054, CM033399, COSV99212489; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR4A15 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59033495; called by muse, mutect2, varscan2
- PKN2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV60129624; called by muse, mutect2, varscan2
- PPFIA1 | c.3272G>T p.S1091I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV54131278; called by muse, mutect2, varscan2
- PRKX | c.348G>A p.W116* | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as rs866666364, COSV53321970; called by muse, mutect2
- RAD17 | c.1402G>T p.V468L (on ENST00000380774 / NM_133339.2; = p.V457L on NM_002873.1) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); catalogued as COSV51456014; called by muse, mutect2
- SLC4A1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs373768879, CM983769, COSV99293058; called by muse, mutect2
- SMARCA1 | c.2978G>C p.R993P | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64410695, COSV64411340; called by muse, mutect2, varscan2
- TTN | c.77878C>A p.P25960T (on ENST00000591111; = p.P18536T on NM_003319.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | PolyPhen benign (0.173); catalogued as COSV59871123; called by muse, mutect2, varscan2
- ZCCHC24 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV64886219; called by muse, mutect2
- RPL11 | c.20del p.K7Rfs*26 (on ENST00000374550 / NM_001199802.1; = p.K8Rfs*26 on NM_000975.5) | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | called by mutect2, pindel, varscan2
- CCDC59 | c.723T>C p.C241= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV56280671; called by muse, mutect2, varscan2
- FBXO30 | c.1623T>G p.G541= | Silent (SNP) | VAF 16/142 reads (11%) | catalogued as COSV52790125; called by muse, mutect2, varscan2
